Somatic mutation profile of tumor specimen TARGET-20-PARVLH-09A (aliquot TARGET-20-PARVLH-09A-01D) from TARGET case TARGET-20-PARVLH, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.4 years (499 days).
Specimen TARGET-20-PARVLH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a8617f2-bf67-4ead-b782-40332f0a417f.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARVLH-14A (Bone Marrow Normal), aliquot TARGET-20-PARVLH-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4ef506f-e687-49c0-8537-68344c9aa007

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 41/111 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ZEB2 | c.3130G>A p.E1044K | Missense Mutation (SNP) | VAF 66/205 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as rs730881202; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EZH2 | c.1999_2007del p.F667_L669del (on ENST00000460911 / NM_001203247.2; = p.F672_L674del on NM_004456.5) | In Frame Del (DEL) | VAF 34/100 reads (34%) | called by pindel, varscan2
- AMER1 | c.*1268G>A | 3'UTR (SNP) | VAF 82/183 reads (45%) | catalogued as rs900303053; called by muse, mutect2, varscan2
